Surgical pathology report (de-identified scan), TCGA case TCGA-4G-AAZR, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Sapienza University of Rome, specimen TCGA-4G-AAZR-01A (Primary Tumor).

pathology report

Date of tumor procurement:

Anatomic site: perihilar

Histology diagnosis: moderately differentiated perihilar cholangiocarcinoma (extrahepatic)

Histological examination

- Right Hepatic lobe containing gallbladder and cystic duct: hepatic resection of 20x20x11.5 cm, characterized by the presence of a whitish nodule of 12x12x12 cm arising from the right hepatic duct. Multiple satellite lesions are also presents. Histologically, the lesions are consistent with a moderately differentiated cholangiocarcinoma arising from the right hepatic duct, presenting invasion of lymphatic vessels and of the gallbladder (G2, pT3 UICC 2009).

ICD O-3
Cholangiocarcinoma 8160/3
Site Extrahepatic bile duct
024.0
Jt 4/22/14

Source: NCI Genomic Data Commons file d04468c0-e502-4c4a-b62b-c4c6d464f790 (TCGA-4G-AAZR.0411F033-20FA-4F8F-AD51-A4EDF3E758BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).